Gene-level copy-number profile of tumor specimen ALCH-B021-TTP1-A from ALCHEMIST case ALCH-B021, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 70.7 years (25,826 days).
Specimen ALCH-B021-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f108cb5f-8e2c-4263-8c10-8653080eefae.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B021-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/fe41bbf9-4f95-4bf4-b5c5-c5685ad8a21c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 515; copy number 1: 598; copy number 2: 20,617; copy number 3: 12,520; copy number 4: 15,116; copy number 5: 3,251; copy number 6: 4,625; copy number 7: 272; copy number 8: 59; copy number 9: 662; copy number 10: 26; copy number 11: 381; copy number 12: 219; copy number 13: 7; copy number 16: 3; copy number 21: 3; copy number 23: 12.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:42,183,659–42,354,454, 5 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.
- chr18:37,305,295–37,306,333, 1 gene (within-gene range 0–2): AC090386.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,520 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–158,203,877, 656 genes, copy number 5–6 (broad region; genes not listed).
- chr1:158,327,951–248,937,043, 1,865 genes, copy number 5–7 (broad region; genes not listed).
- chr2:38,814–94,604,573, 1,601 genes, copy number 5–7 (broad region; genes not listed).
- chr2:154,435,853–155,330,527, 16 genes, copy number 5 (within-gene range 4–5): AC009227.1, AC009227.2, RNA5SP107, AC061961.1, KCNJ3, CBX3P6, AC092625.1, RNU6-1001P, MTCO1P45, MTND2P20, ATP5F1AP2, MTND4P28, MTND5P30, MTND6P9, MTCYBP9, RNU6-546P.
- chr2:170,178,145–219,493,629, 839 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr3:109,293,788–198,123,232, 1,562 genes, copy number 5–13 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 5 (broad region; genes not listed).
- chr7:53,002,420–57,837,046, 156 genes, copy number 6–23 (broad region; genes not listed).
- chr7:73,799,542–73,842,516, 2 genes, copy number 5: CLDN4, METTL27.
- chr9:12,685,439–14,532,042, 23 genes, copy number 5: TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1.
- chr9:42,384,805–42,626,813, 9 genes, copy number 5: FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5.
- chr9:42,830,337–43,045,120, 8 genes, copy number 5: ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr9:63,581,254–63,776,143, 8 genes, copy number 5: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3.
- chr9:65,189,995–65,323,015, 5 genes, copy number 5–8: BMS1P12, AL512605.1, AL512605.2, FOXD4L5, CBWD4P.
- chr9:66,022,661–66,055,006, 4 genes, copy number 5: GXYLT1P4, AL136317.3, AL669942.2, AL669942.1.
- chr9:73,151,865–73,170,393, 1 gene, copy number 5: ANXA1.
- chr10:11,453,946–11,612,227, 2 genes, copy number 5: USP6NL, AL512631.2.
- chr11:1,947,278–1,984,522, 1 gene, copy number 16 (within-gene range 2–16): MRPL23.
- chr11:56,848,478–57,819,546, 43 genes, copy number 5: LINC02735, FADS2B, OR5AK3P, OR5AK2, OR5AK1P, OR5BQ1P, OR5AK4P, OR5AO1P, OR5BP1P, LRRC55, APLNR, TNKS1BP1, AP000781.1, SSRP1, P2RX3, PRG3, PRG2, AP000781.2, SLC43A3, RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1, SLC43A1, RN7SL605P, TIMM10, SMTNL1, UBE2L6, RPS4XP13, SERPING1, AP000662.1, MIR130A, YPEL4, CLP1, ZDHHC5, MED19, AP001931.2, TMX2, PPIAP42, SELENOH, AP001931.1, BTBD18, CTNND1.
- chr11:65,180,566–82,718,299, 550 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr12:104,215,779–104,350,307, 4 genes, copy number 5: TXNRD1, AC089983.1, RPL18AP3, EID3.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:27,621,534–28,457,783, 18 genes, copy number 5: AC021979.1, AC021979.2, OCA2, AC090696.1, RPL5P32, HERC2, RPL41P2, HERC2P1, AC091304.4, AC091304.1, AC091304.3, GOLGA8F, RN7SL238P, ABCB10P3, AC091304.8, AC091304.5, MIR4509-2, AC091304.2.
- chr15:28,506,625–28,508,808, 1 gene, copy number 12: ABCB10P4.
- chr16:11,668,455–11,742,857, 2 genes, copy number 5 (within-gene range 3–5): SNN, TXNDC11.
- chr17:20,008,865–20,319,026, 1 gene, copy number 6 (within-gene range 2–6): SPECC1.
- chr17:20,111,824–21,641,536, 83 genes, copy number 6 (broad region; genes not listed).
- chr17:50,719,565–50,756,219, 2 genes, copy number 6: LUC7L3, AC005921.3.
- chr19:2,269,525–2,341,172, 1 gene, copy number 5 (within-gene range 1–5): AC005258.1.
- chr19:2,293,173–16,496,167, 751 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:16,496,394–16,542,437, 2 genes, copy number 5 (within-gene range 3–5): C19orf44, CHERP.
- chr19:20,432,552–20,571,095, 2 genes, copy number 5 (within-gene range 3–5): AC008554.1, BNIP3P23.
- chr19:33,906,352–35,424,652, 80 genes, copy number 5 (broad region; genes not listed).
- chr19:35,887,653–44,448,452, 433 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:10,612,455–13,016,692, 4 genes, copy number 6: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1.
- chr21:43,446,601–43,479,534, 3 genes, copy number 9: LINC00319, LINC00313, AP001048.1.
- chr22:45,133,020–45,891,438, 22 genes, copy number 5: NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1.
- chr22:48,866,770–50,801,309, 77 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 598. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
